Somatic mutation profile of tumor specimen ALCH-B3DT-TTP1-A (aliquot ALCH-B3DT-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B3DT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,191 days).
Specimen ALCH-B3DT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ee2c8e4-93e3-4c9d-94fa-9f93fa4362af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3DT-NB1-A (Blood Derived Normal), aliquot ALCH-B3DT-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d08cadce-5430-4cdf-aa34-5839bf08def7

The open-access MAF lists 220 somatic variants for this specimen: 146 protein-altering or splice-affecting, 47 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 47, Intron 14, Nonsense Mutation 8, Frame Shift Del 8, RNA 5, 3'UTR 4, Splice Site 4, 5'UTR 2, Splice Region 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-1G>C p.X307_splice | Splice Site (SNP) | VAF 68/194 reads (35%) | hotspot (GDC flag); catalogued as rs587781702, CS0910927, CS114009, COSV52664150, COSV52690279, COSV52737535; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTC1 | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as COSV51757816; called by muse, mutect2, varscan2
- C8A | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV100776622, COSV63485847; called by muse, mutect2, varscan2
- CARD11 | c.1619del p.G540Dfs*60 | Frame Shift Del (DEL) | VAF 17/148 reads (11%) | catalogued as COSV62756480; called by mutect2, pindel, varscan2
- CRACD | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV51720620; called by muse, mutect2
- CSMD3 | c.7372G>A p.A2458T (on ENST00000297405 / NM_001363185.1; = p.A2354T on NM_052900.3) | Missense Mutation (SNP) | VAF 53/474 reads (11%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.964); catalogued as rs1219977067; called by muse, mutect2, varscan2
- DCAF12L1 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64421627; called by muse, mutect2, varscan2
- DNAH7 | c.7315C>T p.Q2439* | Nonsense Mutation (SNP) | VAF 67/340 reads (20%) | catalogued as COSV56786902; called by muse, mutect2, varscan2
- DUSP26 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375557504; called by muse, mutect2
- EPHB2 | c.2560G>A p.A854T (on ENST00000400191 / NM_001309193.2; = p.A855T on NM_004442.7) | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs549199396; called by muse, mutect2, varscan2
- FAM83B | c.2060C>A p.T687K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV100174434; called by muse, mutect2, varscan2
- GALNT9 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as rs370356913; called by muse, mutect2, varscan2
- GNAO1 | c.727C>A p.R243S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52614215, COSV99341769; called by muse, varscan2
- GPR137 | c.399C>G p.S133R | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV57404193; called by muse, mutect2
- GRID2 | c.1889C>G p.T630S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.973); catalogued as COSV56218322; called by muse, mutect2, varscan2
- GRM6 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140082247; called by muse, mutect2
- JMJD1C | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV101232454; called by muse, mutect2
- KEAP1 | c.597G>T p.L199F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99407887; called by muse, mutect2
- LGALS16 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 105/488 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67425345; called by muse, mutect2, varscan2
- MUC17 | c.9007G>A p.E3003K | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV60282203; called by muse, mutect2
- PCDHB9 | c.2227G>T p.G743W | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53384875; called by muse, mutect2
- PCSK1 | c.51C>A p.C17* | Nonsense Mutation (SNP) | VAF 90/359 reads (25%) | catalogued as rs774807858, COSV60733605; called by muse, varscan2
- POT1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62934334; called by muse, mutect2
- POTEE | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 201/853 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376564316; called by muse, mutect2, varscan2
- RALGAPA1 | c.2176G>A p.G726S | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.715); catalogued as rs746296161; called by muse, mutect2
- RGS4 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 85/642 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs761746821; called by muse, mutect2, varscan2
- RPS6KB2 | c.1269C>T p.S423= | Splice Region (SNP) | VAF 10/106 reads (9%) | catalogued as rs201485693; called by muse, mutect2
- RYR1 | c.11908-1G>A p.X3970_splice | Splice Site (SNP) | VAF 82/474 reads (17%) | catalogued as rs768655892; called by muse, mutect2
- SLC17A4 | c.864G>C p.M288I | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as rs199756466, COSV64955662, COSV64955940; called by muse, mutect2, varscan2
- SMARCA4 | c.3580G>A p.G1194R | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1171822727, COSV60789775, COSV60800634; called by muse, mutect2, varscan2
- TEX2 | c.3329G>A p.R1110H (on ENST00000583097 / NM_001288733.2; = p.R1117H on NM_018469.5) | Missense Mutation (SNP) | VAF 20/421 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs778477556, COSV51979048, COSV51982534; called by muse, mutect2
- TLR8 | c.3018C>A p.D1006E (on ENST00000218032 / NM_138636.5; = p.D1024E on NM_016610.4) | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.814); catalogued as rs1211459378; called by muse, mutect2, varscan2
- TMC1 | c.815G>T p.R272M | Missense Mutation (SNP) | VAF 117/502 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52779261; called by muse, mutect2, varscan2
- TTC22 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1018505757; called by muse, mutect2
- TTN | c.10991G>C p.S3664T (on ENST00000591111; = p.S3618T on NM_003319.4) | Missense Mutation (SNP) | VAF 52/345 reads (15%) | catalogued as rs761366397; called by muse, mutect2, varscan2
- TTN | c.5668C>A p.R1890S (on ENST00000591111; = p.R1844S on NM_003319.4) | Missense Mutation (SNP) | VAF 72/376 reads (19%) | PolyPhen possibly damaging (0.51); catalogued as COSV59883492; called by muse, mutect2, varscan2
- USP4 | c.2204G>T p.R735L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs148734128; called by muse, mutect2, varscan2
- WDR59 | c.2018T>C p.I673T | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs780289341; called by muse, mutect2, varscan2
- ZACN | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 15/226 reads (7%) | catalogued as rs752520798; called by muse, mutect2
- ZNF716 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as rs758521328, COSV101348591; called by muse, mutect2
- ADAMTS17 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ADAMTS19 | c.1256A>C p.D419A | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ADD2 | c.152A>T p.K51M | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADGRL3 | c.308C>A p.S103Y (on ENST00000506720 / NM_001322402.2; = p.S35Y on NM_015236.6) | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ALPI | c.156del p.K53Rfs*16 | Frame Shift Del (DEL) | VAF 31/175 reads (18%) | called by mutect2, pindel, varscan2
- AMPD2 | c.1922A>C p.H641P | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ANKRD12 | c.3724A>T p.M1242L | Missense Mutation (SNP) | VAF 93/368 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD26 | c.2921A>G p.Y974C | Missense Mutation (SNP) | VAF 76/433 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- API5 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- APLP1 | c.140C>G p.A47G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.37); called by mutect2, varscan2
- BRDT | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); called by muse, mutect2
- C3orf38 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2
- CACNA2D3 | c.2102G>T p.S701I | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CAPN2 | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CCNB3 | c.1183A>G p.R395G | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2
- CCR4 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDS1 | c.667A>T p.I223L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CFAP74 | c.4013G>A p.G1338D | Missense Mutation (SNP) | VAF 8/227 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLDN17 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COG5 | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- CRYBB1 | c.140C>G p.T47S | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSE1L | c.2854A>G p.N952D | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- CTCFL | c.170A>C p.Q57P | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.348); called by muse, mutect2
- DACH2 | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- DDX27 | c.1917G>C p.K639N | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DHX34 | c.1117T>A p.Y373N | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EDNRB | c.1028G>T p.R343L (on ENST00000377211 / NM_001201397.1; = p.R253L on NM_000115.5) | Missense Mutation (SNP) | VAF 54/389 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EGFR | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2AK3 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 16/596 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- EP400 | c.3388C>T p.L1130F | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- F2RL2 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM102B | c.670T>A p.S224T | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- FAM126A | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FAM169A | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- FBXO41 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCRL5 | c.1210C>A p.Q404K | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- FLG2 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 70/842 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.672); called by muse, mutect2
- FZR1 | c.1427C>G p.T476S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- GMPPA | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- GPR158 | c.2467del p.H823Tfs*2 | Frame Shift Del (DEL) | VAF 34/252 reads (13%) | called by mutect2, pindel, varscan2
- GSX2 | c.757C>G p.R253G | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GUCY2C | c.3041C>T p.P1014L | Missense Mutation (SNP) | VAF 223/535 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA12A | c.1459G>C p.A487P | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- HSPA12A | c.1458G>T p.E486D | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HSPG2 | c.5855G>T p.G1952V | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); called by muse, mutect2
- IFIH1 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IGHV1-58 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 137/531 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- IWS1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KDM5C | c.2615A>T p.D872V | Missense Mutation (SNP) | VAF 92/437 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- KLF12 | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); called by muse, mutect2
- MIDEAS | c.743A>G p.Q248R | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.024); called by muse, varscan2
- NAT2 | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2
- NAV3 | c.2186C>A p.T729N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- NBPF4 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.22); called by mutect2, varscan2
- NDUFB4 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- NLRP1 | c.1214T>C p.L405P | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NTRK3 | c.275A>C p.H92P | Missense Mutation (SNP) | VAF 81/582 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OGFRL1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2
- OR10Z1 | c.808A>T p.R270* | Nonsense Mutation (SNP) | VAF 112/535 reads (21%) | called by muse, mutect2, varscan2
- OR11G2 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- OR14A16 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2
- OR52E6 | c.569C>A p.A190D | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OR56A4 | c.1090A>T p.R364W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- OR5B2 | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- OVCH1 | c.27G>T p.L9F | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PCDHB9 | c.2228G>T p.G743V | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PEX5 | c.204G>T p.Q68H | Missense Mutation (SNP) | VAF 50/1060 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- PHEX | c.1098G>T p.L366F | Missense Mutation (SNP) | VAF 102/422 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PHF14 | c.1430dup p.L478Afs*19 | Frame Shift Ins (INS) | VAF 41/363 reads (11%) | called by mutect2, pindel, varscan2
- PIWIL1 | c.1004C>A p.A335D | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.404); called by muse, varscan2
- POLR3A | c.2248-1G>A p.X750_splice | Splice Site (SNP) | VAF 75/496 reads (15%) | called by muse, mutect2, varscan2
- POM121L12 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POM121L2 | c.2632G>C p.G878R | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PPP2R2D | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RABEP2 | c.1353G>T p.E451D | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- RYR3 | c.7796C>A p.P2599Q (on ENST00000389232; = p.P2600Q on NM_001036.6) | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAP130 | c.1925del p.P642Qfs*86 | Frame Shift Del (DEL) | VAF 43/247 reads (17%) | called by mutect2, pindel, varscan2
- SEL1L2 | c.1972A>T p.K658* | Nonsense Mutation (SNP) | VAF 16/171 reads (9%) | called by muse, mutect2
- SEPTIN4 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 25/258 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.3889-2A>T p.X1297_splice | Splice Site (SNP) | VAF 34/345 reads (10%) | called by muse, mutect2
- SIN3A | c.2464G>T p.D822Y | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC2A1 | c.680T>A p.V227E | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.374); called by muse, mutect2
- SLC9A1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 34/527 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2
- SMIM14 | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- STIM1 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 135/454 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STK11 | c.365del p.K122Sfs*7 | Frame Shift Del (DEL) | VAF 18/143 reads (13%) | called by mutect2, pindel, varscan2
- TAF4B | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- TATDN2 | c.1924A>T p.M642L | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.139); called by muse, mutect2
- TENM4 | c.6646A>T p.S2216C | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TET2 | c.3829G>T p.D1277Y | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TFCP2L1 | c.565_574del p.F189Rfs*76 | Frame Shift Del (DEL) | VAF 28/315 reads (9%) | called by mutect2, pindel
- THBS2 | c.1071_1083del p.A358Vfs*34 | Frame Shift Del (DEL) | VAF 35/242 reads (14%) | called by mutect2, pindel, varscan2
- THSD7B | c.2449C>A p.Q817K | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TMEM132E | c.2309C>A p.A770D (on ENST00000321639; = p.A860D on NM_001304438.2) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM161B | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNR | c.1370del p.G457Efs*2 | Frame Shift Del (DEL) | VAF 29/164 reads (18%) | called by mutect2, pindel, varscan2
- TNS2 | c.4092G>A p.K1364= (on ENST00000314250 / NM_170754.4; = p.K1374= on NM_015319.2) | Splice Region (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- TPST1 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UQCRFS1 | c.487A>T p.K163* | Nonsense Mutation (SNP) | VAF 32/323 reads (10%) | called by muse, mutect2, varscan2
- VWDE | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XIRP2 | c.445G>T p.V149F (on ENST00000628543; = p.V324F on NM_152381.6) | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- ZFYVE9 | c.2775G>C p.Q925H | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2
- ZNF223 | c.1224C>A p.S408R | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.822); called by muse, mutect2
- ZNF585B | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 145/537 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ZNF735 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 75/449 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ZSCAN31 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 53/301 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM12 | c.711T>A p.V237= | Silent (SNP) | VAF 50/264 reads (19%) | called by muse, mutect2, varscan2
- AHNAK2 | c.14334C>T p.H4778= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs751775165; called by muse, mutect2
- AKAP9 | c.11532G>C p.L3844= (on ENST00000359028; = p.L3820= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/381 reads (18%) | called by muse, mutect2, varscan2
- ALG13 | c.1890A>T p.S630= | Silent (SNP) | VAF 73/462 reads (16%) | called by muse, mutect2, varscan2
- ARHGEF39 | c.172C>T p.L58= | Silent (SNP) | VAF 13/190 reads (7%) | catalogued as COSV100526289; called by muse, mutect2
- ATG5 | c.303A>T p.T101= | Silent (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- BDP1 | c.3009G>A p.K1003= | Silent (SNP) | VAF 22/360 reads (6%) | catalogued as rs369046194; called by muse, mutect2
- CARD17 | c.267C>T p.L89= | Silent (SNP) | VAF 36/148 reads (24%) | called by muse, mutect2, varscan2
- CLEC4D | c.63G>T p.S21= | Silent (SNP) | VAF 48/598 reads (8%) | catalogued as COSV100223037; called by muse, mutect2
- COL11A1 | c.2349T>C p.D783= | Silent (SNP) | VAF 48/386 reads (12%) | catalogued as rs756163217; called by muse, varscan2
- DDX50 | c.1962A>T p.I654= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV65292387; called by muse, mutect2, varscan2
- EIPR1 | c.321A>T p.S107= | Silent (SNP) | VAF 40/220 reads (18%) | called by muse, mutect2, varscan2
- FADS2 | c.408C>A p.L136= | Silent (SNP) | VAF 26/657 reads (4%) | called by muse, mutect2
- FFAR1 | c.669C>A p.A223= | Silent (SNP) | VAF 63/281 reads (22%) | called by muse, mutect2, varscan2
- H1-8 | c.798G>T p.T266= | Silent (SNP) | VAF 19/224 reads (8%) | called by muse, mutect2
- HAO1 | c.1011G>A p.K337= | Silent (SNP) | VAF 19/251 reads (8%) | catalogued as COSV101113204; called by muse, mutect2
- IQCF2 | c.246G>T p.S82= | Silent (SNP) | VAF 37/389 reads (10%) | called by muse, mutect2
- ITIH5 | c.1800G>T p.R600= | Silent (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- KCNA1 | c.948C>A p.G316= | Silent (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2, varscan2
- LGI4 | c.228G>A p.P76= | Silent (SNP) | VAF 40/261 reads (15%) | catalogued as rs750524905; called by muse, mutect2, varscan2
- MAN2A2 | c.2016C>T p.R672= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as rs201501980, COSV64637244; called by muse, mutect2, varscan2
- MAP3K13 | c.2601A>T p.S867= | Silent (SNP) | VAF 19/537 reads (4%) | called by muse, mutect2
- MAST2 | c.4453C>A p.R1485= | Silent (SNP) | VAF 41/138 reads (30%) | called by muse, mutect2, varscan2
- MED23 | c.2364C>G p.L788= | Silent (SNP) | VAF 35/516 reads (7%) | catalogued as COSV63432489; called by muse, mutect2
- MS4A14 | c.1453C>A p.R485= | Silent (SNP) | VAF 94/344 reads (27%) | catalogued as rs376488191; called by muse, mutect2, varscan2
- NNAT | c.57C>T p.F19= | Silent (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2, varscan2
- NR2F2 | c.1062C>T p.P354= | Silent (SNP) | VAF 20/456 reads (4%) | called by muse, mutect2
- PCDH11X | c.1080C>A p.I360= | Silent (SNP) | VAF 45/228 reads (20%) | catalogued as rs751968718, COSV100016221; called by muse, mutect2, varscan2
- PCDHA13 | c.223C>T p.L75= | Silent (SNP) | VAF 22/687 reads (3%) | catalogued as rs782462724; called by muse, mutect2
- PIEZO2 | c.3873G>T p.V1291= | Silent (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- PKD1L2 | c.2676C>T p.P892= | Silent (SNP) | VAF 11/193 reads (6%) | catalogued as rs373451830; called by muse, mutect2
- RNF13 | c.177T>A p.L59= | Silent (SNP) | VAF 39/141 reads (28%) | called by muse, mutect2, varscan2
- RNF182 | c.219G>C p.L73= | Silent (SNP) | VAF 62/417 reads (15%) | called by muse, mutect2, varscan2
- RPRD2 | c.4296A>T p.P1432= | Silent (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- RRAD | c.918G>T p.S306= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs368384610; called by muse, varscan2
- SATB2 | c.834C>T p.H278= | Silent (SNP) | VAF 15/214 reads (7%) | called by muse, mutect2
- SLC25A45 | c.135G>A p.K45= | Silent (SNP) | VAF 28/247 reads (11%) | called by muse, mutect2, varscan2
- SOCS2 | c.426C>T p.A142= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs1466952116; called by muse, mutect2, varscan2
- SORCS1 | c.1113G>A p.L371= | Silent (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- SRRT | c.522C>T p.D174= | Silent (SNP) | VAF 45/216 reads (21%) | called by muse, mutect2, varscan2
- TEX13C | c.1851C>A p.P617= | Silent (SNP) | VAF 126/652 reads (19%) | called by muse, mutect2, varscan2
- TP53BP2 | c.693G>A p.Q231= (on ENST00000343537 / NM_001031685.3; = p.Q102= on NM_005426.2) | Silent (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- TRIM46 | c.1728G>C p.L576= | Silent (SNP) | VAF 55/536 reads (10%) | catalogued as COSV100104842, COSV58113449; called by muse, mutect2
- TTN | c.24216T>A p.L8072= (on ENST00000591111; = p.L7145= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/266 reads (15%) | called by muse, mutect2, varscan2
- TTYH3 | c.363G>T p.S121= | Silent (SNP) | VAF 18/155 reads (12%) | called by muse, mutect2, varscan2
- URGCP | c.2535G>A p.L845= (on ENST00000453200 / NM_001077663.3; = p.L836= on NM_017920.4) | Silent (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- YME1L1 | c.882T>C p.R294= (on ENST00000326799 / NM_139312.3; = p.R237= on NM_014263.4) | Silent (SNP) | VAF 30/324 reads (9%) | called by muse, mutect2
- AC005863.1 | n.276G>A | RNA (SNP) | VAF 14/70 reads (20%) | catalogued as rs1282529087; called by muse, varscan2
- AC244517.10 | c.36-9306G>C | Intron (SNP) | VAF 22/382 reads (6%) | called by muse, mutect2
- ATXN2 | c.3744+980A>T | Intron (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- COL6A2 | c.735+34C>A | Intron (SNP) | VAF 51/270 reads (19%) | called by muse, mutect2, varscan2
- DGCR2 | c.625+2292C>T | Intron (SNP) | VAF 18/58 reads (31%) | catalogued as rs1199498013; called by muse, mutect2
- FMO9P | n.569G>A | RNA (SNP) | VAF 28/208 reads (13%) | called by muse, mutect2, varscan2
- FXYD2 | c.65-15C>A | Intron (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- GLOD4 | chr17:782367 G>C | 5'Flank (SNP) | VAF 64/187 reads (34%) | called by muse, mutect2, varscan2
- KCNN3 | c.-53G>A | 5'UTR (SNP) | VAF 37/144 reads (26%) | called by muse, mutect2, varscan2
- MBD1 | c.*120C>T | 3'UTR (SNP) | VAF 23/252 reads (9%) | called by muse, mutect2
- MED14 | c.*2206_*2208del | 3'UTR (DEL) | VAF 12/115 reads (10%) | called by mutect2, pindel, varscan2
- MIR612 | n.14C>A | RNA (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
- MYCN | c.*2C>T | 3'UTR (SNP) | VAF 39/389 reads (10%) | catalogued as rs141392135; called by muse, mutect2, varscan2
- NAA38 | c.82-71G>T | Intron (SNP) | VAF 15/75 reads (20%) | catalogued as rs757081757; called by muse, mutect2, varscan2
- NPIPB14P | n.662T>C | RNA (SNP) | VAF 28/768 reads (4%) | called by muse, mutect2
- NTHL1 | c.709+47G>T | Intron (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- PPFIA1 | c.1931+2079G>T | Intron (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- PPP1R3C | c.-61G>C | 5'UTR (SNP) | VAF 12/326 reads (4%) | called by muse, mutect2
- PSMD2 | c.480-18G>T | Intron (SNP) | VAF 51/248 reads (21%) | catalogued as rs376549573; called by muse, mutect2, varscan2
- PTPN12 | c.2143-23G>A | Intron (SNP) | VAF 30/151 reads (20%) | catalogued as rs746505577; called by muse, mutect2, varscan2
- RAD51C | c.705+3197G>T | Intron (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- SNORD115-23 | n.58A>T | RNA (SNP) | VAF 33/283 reads (12%) | called by muse, mutect2, varscan2
- SPCS3 | c.295-35G>A | Intron (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- TMEM135 | c.*1134T>C | 3'UTR (SNP) | VAF 21/785 reads (3%) | called by muse, mutect2
- TPD52L1 | c.20-80A>G | Intron (SNP) | VAF 92/309 reads (30%) | called by muse, mutect2, varscan2
- Unknown | chr21:16194469 G>T | IGR (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- VPS13B | c.4820+15694C>G | Intron (SNP) | VAF 42/508 reads (8%) | called by muse, mutect2
